Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LJ, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LJ-01A (Primary Tumor).

[page 1 of 2]
Procedure: most likely adrenalectomy

Reference Pathology only:

Diagnosis: adrenocortical carcinoma, 2 per 10 hpf

ICD O-3
Tumor, Adrenal Cortical
of unknown/uncertain behavior
8370.3
Site: Adrenal Gland cortex
C74.0
JW 2/6/13

Process - if case passes we can request
more path. May not ship if not
malignant,

HPVAA Discrepancy		

[page 2 of 2]
Patient # from Tissue Source Site

Date of report

Date of Surgery/specimen collection

Site (confirmed to be adrenal) with laterality indicated

Tumor size(s)

Histologic diagnosis
ACC

Lymph Node Status

Pathologic information

Weiss score

Source: NCI Genomic Data Commons file 48def6d1-dab2-4381-aef3-6522bc9d4419 (TCGA-OR-A5LJ.B93073AF-A15A-4BAB-AC70-E16D89256DFC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).